Somatic mutation profile of tumor specimen 0DUETV from CCDI case PBCLCG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Pineoblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.7 years (1,340 days).
Specimen 0DUETV: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 95e959aa-d9b9-4ee1-be35-dc25f46f0961.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUETM (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1bace3cf-afef-4f49-97ff-db07174b2649

The open-access MAF lists 28 somatic variants for this specimen: 14 protein-altering or splice-affecting, 6 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 6, 3'UTR 3, Intron 3, 3'Flank 1, Splice Region 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXL6 | c.576-7G>A | Splice Region (SNP) | VAF 51/268 reads (19%) | catalogued as rs557063176; called by muse, mutect2, varscan2
- KLHL22 | c.1654C>T p.R552C | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56732999, COSV99839165; called by muse, mutect2, varscan2
- OBSCN | c.17785C>G p.L5929V | Missense Mutation (SNP) | VAF 81/225 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs369259497; called by muse, mutect2, varscan2
- PLA2G12B | c.523C>T p.R175C | Missense Mutation (SNP) | VAF 56/753 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs369052687; called by muse, mutect2
- PTPRT | c.3271A>C p.T1091P | Missense Mutation (SNP) | VAF 24/358 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61983220; called by muse, mutect2
- RNF148 | c.286A>G p.K96E | Missense Mutation (SNP) | VAF 196/698 reads (28%) | SIFT tolerated (0.92); PolyPhen benign (0.003); catalogued as rs369956136; called by muse, mutect2, varscan2
- BCL7B | c.436G>C p.E146Q | Missense Mutation (SNP) | VAF 73/256 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- C10orf71 | c.3293C>A p.P1098H | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- F9 | c.805G>T p.V269F | Missense Mutation (SNP) | VAF 27/274 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2
- JAK2 | c.2580T>G p.F860L | Missense Mutation (SNP) | VAF 117/227 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- LHX8 | c.986A>T p.Y329F | Missense Mutation (SNP) | VAF 106/322 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SCNN1G | c.629A>T p.D210V | Missense Mutation (SNP) | VAF 154/340 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- SOBP | c.2611C>A p.Q871K | Missense Mutation (SNP) | VAF 17/223 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- ZBTB37 | c.1078C>A p.Q360K | Missense Mutation (SNP) | VAF 167/365 reads (46%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- EML4 | c.1051C>T p.L351= | Silent (SNP) | VAF 50/957 reads (5%) | called by muse, mutect2
- KRT40 | c.327C>T p.S109= | Silent (SNP) | VAF 132/268 reads (49%) | called by muse, mutect2
- PHLPP1 | c.753G>T p.G251= | Silent (SNP) | VAF 8/81 reads (10%) | catalogued as COSV99408292; called by muse, mutect2, varscan2
- SLC12A6 | c.405C>T p.L135= (on ENST00000354181 / NM_001365088.1; = p.L84= on NM_005135.2) | Silent (SNP) | VAF 41/344 reads (12%) | catalogued as COSV51624996, COSV99272974; called by muse, mutect2, varscan2
- SYNE1 | c.10260G>A p.A3420= (on ENST00000367255 / NM_182961.4; = p.A3427= on NM_033071.3) | Silent (SNP) | VAF 206/481 reads (43%) | catalogued as rs145287138; ClinVar: benign / uncertain significance; called by muse, mutect2, varscan2
- VAV1 | c.303T>C p.D101= | Silent (SNP) | VAF 232/492 reads (47%) | catalogued as rs1026155299; called by muse, mutect2, varscan2
- CC2D2B | c.657+32A>C | Intron (SNP) | VAF 42/50 reads (84%) | called by muse, mutect2, varscan2
- KARS1 | c.388+59G>T | Intron (SNP) | VAF 4/42 reads (10%) | called by muse, mutect2
- RPL27A | c.-1C>T | 5'UTR (SNP) | VAF 94/267 reads (35%) | catalogued as rs754250435; called by muse, mutect2, varscan2
- RPS17 | c.*1311C>G | 3'UTR (SNP) | VAF 76/378 reads (20%) | called by muse, mutect2, varscan2
- SLC43A3 | c.185-91C>T | Intron (SNP) | VAF 8/81 reads (10%) | catalogued as rs943613069; called by muse, mutect2, varscan2
- SNTB1 | c.*85C>T | 3'UTR (SNP) | VAF 20/58 reads (34%) | catalogued as rs1025837203; called by muse, mutect2
- SZT2 | c.*3386G>T | 3'UTR (SNP) | VAF 14/43 reads (33%) | called by muse, mutect2, varscan2
- UBXN11 | chr1:26282219 G>C | 3'Flank (SNP) | VAF 4/36 reads (11%) | called by muse, mutect2
